Gene-level copy-number profile of tumor specimen TCGA-IB-AAUO-01A from TCGA case TCGA-IB-AAUO, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 64.7 years (23,622 days).
Specimen TCGA-IB-AAUO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.3ab21b75-d3a3-4e1b-8233-63a86e06109d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IB-AAUO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/578c2fa0-e2de-4c09-8f8f-26d97603a1e6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 13,437; copy number 2: 44,776; copy number 3: 6; copy number 4: 1,589.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IB-AAUO-01A-12D-A38F-01): tumor purity 0.34, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:1,312,098–1,395,603, 5 genes: FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720.
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 11,016. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
